Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8212, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8212-01B (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Right pelvic lymph nodes:

Two benign hyperplastic lymph nodes.

B. Left pelvic lymph node:

Benign, hyperplasia.

C. Radical prostatectomy:

Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type.
2. Gleason Grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Score: 7/10.
3. Tumor involves: Both lobes.
4. Tumor quantitation: Estimated 30%.
5. Seminal vesicle involvement: No.
6. Extra-capsular tumor extension: Yes, focal, left posterior region.
7. Lympho-vascular space invasion: Present.
8. Perineural space invasion: Present.
9. High grade PIN: Present.
- Surgical Margin Status:
1. Bladder Neck: Negative.
2. Apical (inferior): Negative.
3. Inked prostatic margin: Negative.
- Lymph Node Status:
1. Total number of lymph nodes examined (specimens A and B): 3.
2. Number of lymph nodes containing metastatic carcinoma: None.
- Other significant findings:
1. Frozen section correlation statement: None.
2. Other findings: Benign prostatic hyperplasia.
3. pTNM stage: pT3a, N0, MX.

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right pelvic lymph nodes
- B. Left pelvic lymph node
- C. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

- A. Part A received in formalin labeled [REDACTED] and #1 right lymph nodes is a 4.7 x 2.6 x 0.5 cm irregular fibroadipose tissue, bearing two irregular tan yellow to pink firm tissues, consistent with lymph nodes, measuring 1.8 x 1.2 x 0.2 cm and 2.9 x 1.7 x 0.3 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety as labeled: 1—one lymph node, bisected; 2 to 4—one lymph node, serially sectioned. The blocks are labeled [REDACTED]
- B. Part B received in formalin labeled [REDACTED] and #2 is a 3.6 x 1.7 x 0.4 cm irregular fibroadipose tissue, bearing a 3.1 x 1.4 x 0.4 cm irregular tan pink to yellow firm tissue, consistent with lymph node. The specimen is serially sectioned and representative sections are submitted, to include the lymph node in its entirety in four cassettes labeled [REDACTED]
- C. Part C received in formalin labeled [REDACTED] and #3 is a 40 gram prostatectomy specimen, consisting of a previously sectioned 5.2 x 4.1 x 2.8 cm prostate, a 1.1 x 0.7 x 0.3 cm right seminal vesicle, a 1.1 x 0.6 x 0.3 cm left seminal vesicle, a 0.8 x 0.2 cm probable right vas deferens, and a 0.8 x 0.2 cm probable left vas deferens. The capsule is shaggy, tan pink, and the left side is inked blue and the right red. The red ink is over inked with black. The cut surface consists of tan pink to yellow parenchyma. The specimen is serially sectioned and representative sections are submitted as labeled: 1—left apical margin (perpendicular); 2—right apical margin (perpendicular); 3—left base margin (perpendicular); 4—right base margin (perpendicular); 5—left posterior apex; 6—right posterior apex; 7—left anterior apex; 8—right anterior apex; 9—left posterior mid; 10—right posterior mid; 11—left anterior mid; 12—right anterior mid; 13—left posterior base; 14—right posterior base; 15—left anterior base; 16—right anterior base; 17—left vas deferens margin and left seminal vesicle junction with prostate; 18—right vas deferens margin and right seminal vesicle junction with prostate. The blocks are labeled [REDACTED]. Also received in the same container is a green and yellow cassette labeled [REDACTED]

Source: NCI Genomic Data Commons file 10cf6aec-19a4-416b-8d55-fd1f8e2b98dc (TCGA-HC-8212.B1B14B69-85F9-4DCA-A58F-85B5F28B6443.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).